Surgical pathology report (de-identified scan), TCGA case TCGA-AR-A24X, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Mayo, specimen TCGA-AR-A24X-01A (Primary Tumor).

Final Diagnosis

Breast, right, simple mastectomy: Invasive ductal and lobular carcinoma (mixed features), Nottingham grade II (of III) [tubules 2/3, nuclei 2/3, mitoses 1/3; Nottingham score 5/9], forming a mass, 2.1 x 1.4 x 1.3 cm, with associated biopsy site changes, located in the superior/central region of the breast [AJCC pT2]. A second biopsy site is present in the subareolar region. A separate nodule of ductal carcinoma in situ, 0.6 x 0.6 x 0.5 cm, is present in the upper inner quadrant. Lobular carcinoma in situ is identified. The tumor does not involve the nipple, overlying skin, or underlying chest wall. All surgical resection margins, including the deep margin, are negative for tumor (minimum tumor free margin, 0.5 cm, anterior/superior margin).

Lymph nodes, right axillary sentinel, excision: Multiple (7) right axillary sentinel lymph nodes are negative for metastatic carcinoma [AJCC pN0 (i-) (sn)]. Blue dye is not identified in any of the seven right axillary sentinel lymph nodes. Immunohistochemical cytokeratin stain was performed on the paraffin embedded sentinel lymph node tissue and confirms the H&E impression.

Breast, left, simple mastectomy: Mild proliferative changes characterized by ductal hyperplasia without atypia. The prior biopsy site is identified. The nipple is without diagnostic abnormalities.

Estrogen and progesterone receptor analysis and Her-2/NEU have been ordered on paraffin-embedded tissue.

1CD-0-3

carcinoma, infiltrating ductal and lobular 8522/3

Site: breast, nos C50.9 lw 4/25/11

Source: NCI Genomic Data Commons file aa9d479d-714e-465c-9c62-e5fc9e4a65a7 (TCGA-AR-A24X.B537A19C-C7E8-42EB-BA3F-673417F3A9BA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).